Surgical pathology report (de-identified scan), TCGA case TCGA-DS-A7WI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-DS-A7WI-01A (Primary Tumor).

[page 1 of 4]
Patient:

Hospital No:
Date of Birth:
Age/Sex:

Location:

Pathologist:
Assistant:
Date of Procedure:
Date Received

Accession Number:

Ordering M.D.:

Copies To:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. LYMPH NODE, RIGHT PELVIC (EXCISION):

- Five negative lymph nodes (0/5)

B. LYMPH NODE, RIGHT OBTURATOR (EXCISION):

- Two negative lymph nodes (0/2)

C. LYMPH NODE, LEFT PELVIC (EXCISION):

- Three negative lymph nodes (0/3)

D. LYMPH NODE, LEFT OBTURATOR (EXCISION):

- Metastatic carcinoma in one of five lymph nodes (1/5)

E. UTERUS AND CERVIX (HYSTERECTOMY):

- Cervix:
- Invasive squamous cell carcinoma, non keratinizing, moderately differentiated
- Site: cervix and lower uterine segment, circumferential
- Size: 7.8 cm
- Depth of invasion: 1.1 cm in the cervix, and approximately 2.0 cm in the lower uterine segment
- Lymphovascular invasion: present
- Margins: negative (vaginal, deep, parametrial)
- Endometrium:
- Stromal breakdown
- Benign polyp in lower uterine segment, partially involved by tumor
- Myometrium:
- Leiomyoma (0.5 cm)
- Serosa:
- Fibrinous adhesions

SYNOPTIC REPORT:

Applies To:

A : RIGHT PELVIC LYMPH NODE
B : RIGHT OBTURATOR
C : LEFT PELVIC LYMPH NODE
D : LEFT OBTURATOR
E : UTERUS AND CERVIX

ICD-O-3
Carcinoma, squamous non-
keratinizing 8072/3

Site Cervix NOS
C53.9

9/11/12/13

Patient Case(s).

[page 2 of 4]
PATIENT:

ACCESSION #:

Macroscopic

Specimen Type: Entire uterus
Procedure: Modified radical hysterectomy (type II)
Lymph Node Sampling: Pelvic lymph nodes
Obturator

Microscopic

Histologic Type: Squamous cell carcinoma, nonkeratinizing
Histologic Grade: G2: Moderately differentiated
Tumor Site: Circumferential (all 4 quadrants)
Tumor Size: Dimensions: 7.8 x 7.5 x 1.4cm
Lymphovascular Invasion: Present
Margins: Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin:
0.2 cm
Closest margin: posterior paracervical

Pathologic Staging (pTNM) (AJCC 7th Edition, 2010) (FIGO)

Primary Tumor (pT): pT2a2 [IIA2]: Clinically visible lesion more than 4.0 cm in greatest dimension
Regional Lymph Nodes (pN): pN1: Regional lymph node metastasis
Number of lymph nodes identified: 15
Number of lymph nodes involved: 1

HISTORY:

None provided.

Per WebVS: Five cm sized cervical tumor. By report, cervical biopsies in were positive for squamous cell carcinoma.

MICROSCOPIC FINDINGS:

See diagnosis.

GROSS:

A. RIGHT PELVIC LYMPH NODE

Patient name, label:

designated "right pelvic lymph node"

Specimen type:

Lymph node sampling

Received:

In formalin

Specimen contents:

Adipose tissue and lymph nodes

Number of pieces of tissue:

Multiple

Size of specimen:

1.7 x 1.5 x 0.4 cm

Number of lymph nodes:

1

Size of lymph nodes:

0.7 cm maximum dimension

Tumor:

No gross tumor is seen.

Additional findings:

None

Entirely submitted.

Slide key:

A1. Possible lymph node – 1

A2. Remaining tissue – multiple

SURGICAL PATHOLOGY REPORT

[page 3 of 4]
PATIENT:

ACCESSION #:

B. RIGHT OBTURATOR

Patient name, label:	designated "right obturator"
Specimen type:	Lymph node sampling
Received:	In formalin
Specimen contents:	Adipose tissue and lymph nodes
Number of pieces of tissue:	3
Size of specimen:	4.2 x 2.7 x 1.0 cm
Number of lymph nodes:	2
Size of lymph nodes:	1.7 and 2.6 cm in greatest dimension
Tumor:	No gross tumor is seen.
Additional findings:	None

Entirely submitted.

Slide key:

B1. One lymph node with additional soft tissue, bisected – 2
B2, B3. One lymph node, bisected – 2 each

C. LEFT PELVIC LYMPH NODE

Patient name, label:	designated "left pelvic lymph node"
Specimen type:	Lymph node sampling
Received:	In formalin
Specimen contents:	Adipose tissue and lymph nodes
Number of pieces of tissue:	4
Size of specimen:	2.7 x 1.8 x 0.5 cm
Number of lymph nodes:	3
Size of lymph nodes:	Ranging from 1.0 to 1.6 cm
Tumor:	No gross tumor is seen.
Additional findings:	None

Entirely submitted

Slide key:

C1. Three possible lymph nodes – 3
C2. Remaining tissue – 1

D. LEFT OBTURATOR

Patient name, label:	designated "left obturator"
Specimen type:	Lymph node dissection
Received:	In formalin
Specimen contents:	Adipose tissue and lymph nodes
Number of pieces of tissue:	1
Size of specimen:	7.3 x 2.1 x 1.2 cm
Number of lymph nodes:	5
Size of lymph nodes:	Ranges from 0.3 to 2.4 cm in maximum dimension
Tumor:	One of the lymph nodes shows changes suspicious for metastatic tumor.
Additional findings:	None

The lymph nodes are entirely submitted.

Slide key:

D1. Two lymph nodes - 2

[page 4 of 4]
PATIENT:

ACCESSION #:

- D2. One lymph node, bisected – 2
D3. One lymph node suspicious for metastatic tumor, bisected – 2
D4. One lymph node – 1

E. UTERUS, CERVIX

Labeled designated "uterus, cervix", and received fresh and subsequently pinned and fixed in formalin is a 246 gram, intact hysterectomy specimen. The uterus measures 12.2 x 7.6 x 5.8 cm. The cervix measures 6.2 cm long and up to 6.0 cm in diameter. The vaginal cuff along the anterior aspect extends up to 1.2 cm away from the cervix and along the posterior aspect extends up to 1.6 cm away from the cervix. The endometrial cavity measures 3.5 cm wide and 5.7 cm long. The endometrium ranges in thickness from 0.2 to 0.4 cm in maximum thickness. The myometrium ranges in thickness from 1.0 to 2.8 cm in maximum thickness. The right paracervical soft tissues extend up to 1.4 cm away from the cervix and the left paracervical soft tissues extend up to 1.6 cm away from the cervix.

The serosa is smooth, glistening and red-tan. Within the cervix there is a large, fungating, pink-tan focally necrotic mass with areas of hemorrhage present measuring 7.8 x 7.5 x 1.4 cm. The mass is fully circumferential with possible involvement of the anterior and posterior lower uterine segments. The cut surface of the mass reveals semifirm pale tan tissue intermixed mucous filled cyst that range from 0.3 to 0.7 cm in greatest dimension. Also the mass also grossly invades greater than 50% of the cervical stroma and comes within 0.2 cm of the inked serosa and 0.7 cm of the vaginal cuff resection margin. The paracervical soft tissues appear grossly free of tumor. No additional lesions are identified.

The remaining endometrium is focally granular with pinpoint areas of hemorrhage. The myometrium consists of soft to rubbery pink-tan tissue. Along the uterine fundus one subserosal leiomyoma is identified measuring 0.5 cm in greatest dimension. No polyps are identified. The paracervical soft tissues are entirely submitted. A portion of the tumor from the 3:00 position of the cervix and normal endometrium from the fundus are released to the biorepository for possible future studies. Representative sections of remaining tissue are submitted. Gross photos are taken.

Ink key:

Blue: Anterior

Black: Posterior

Slide key:

- E1, E2. Left paracervical soft tissues, perpendicular sections – multiple each
E3, E4. Right paracervical soft tissues, perpendicular sections – multiple each
E5, E6. Posterior vaginal cuff margin, perpendicular sections – 5, 4
E7, E8. Anterior vaginal cuff margin, perpendicular sections – 4 each
E9. Subserosal leiomyoma – 1
E10. Anterior uterine corpus – 1
E11. Posterior uterine corpus – 1
E12. Additional section of anterior lower uterine segment – 1
E13, E14. Possible mass within posterior lower uterine segment – 1 each
E15-E17. Mass at 12:00 position in relationship to the anterior lower uterine segment, trisected – 1 each
E18. Mass at 3:00 position – 1
E19. Mass in relationship to 9:00 position – 1
E20-E23. Mass at 6:00 position in relationship to lower uterine segment, serially sectioned – 1 each

Gross dictated by

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 5f572ee6-0c59-4f88-9398-f1e7fac15a82 (TCGA-DS-A7WI.4538B5EA-E6C8-4EEA-8387-A1E3C5A754F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).